Somatic mutation profile of tumor specimen MP2PRT-PARCLW-TMP1-A (aliquot MP2PRT-PARCLW-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PARCLW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,200 days).
Specimen MP2PRT-PARCLW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba9125d8-e9b1-41c1-9f1e-7ed547998517.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARCLW-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARCLW-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43891c37-e9ca-4efc-905d-d13bc3b7545e

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Nonsense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCYAP1R1 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 101/300 reads (34%) | catalogued as rs142088943, COSV100417101; called by muse, mutect2, varscan2
- HTR5A | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 182/527 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs200887444; called by muse, mutect2, varscan2
- PCDHB7 | c.2021C>T p.P674L | Missense Mutation (SNP) | VAF 62/2340 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.226); catalogued as rs781787105, COSV50782999; called by muse, mutect2
- COL22A1 | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 167/472 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- EWSR1 | c.1090T>A p.Y364N | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FBXO4 | c.461C>A p.S154* | Nonsense Mutation (SNP) | VAF 14/223 reads (6%) | called by muse, mutect2
- FOLH1 | c.2182G>T p.V728L | Missense Mutation (SNP) | VAF 17/299 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); called by muse, mutect2
- NHLH2 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 52/850 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- SHROOM4 | c.1253C>A p.A418E | Missense Mutation (SNP) | VAF 78/672 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SLC41A3 | c.1024C>A p.H342N | Missense Mutation (SNP) | VAF 60/480 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TNXB | c.8254G>C p.E2752Q (on ENST00000647633; = p.E2505Q on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.611); called by muse, mutect2
- ZDHHC15 | c.337A>G p.M113V | Missense Mutation (SNP) | VAF 16/257 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- FOXG1 | c.624C>T p.Y208= | Silent (SNP) | VAF 38/602 reads (6%) | catalogued as rs267606826, CM100363; called by muse, mutect2
- INSYN2A | c.1128C>A p.I376= | Silent (SNP) | VAF 87/302 reads (29%) | catalogued as COSV54753275; called by muse, mutect2, varscan2
